Gene-level copy-number profile of tumor specimen TCGA-NC-A5HG-01A from TCGA case TCGA-NC-A5HG, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.2 years (21,608 days).
Specimen TCGA-NC-A5HG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3bf45d60-b5f0-4b6d-8aa0-1096e04c6b5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48838c4b-eea7-4e91-aee5-e091e57bc7cb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 140; copy number 2: 15,794; copy number 3: 12,065; copy number 4: 23,468; copy number 5: 4,406; copy number 6: 2,314; copy number 7: 735; copy number 8: 297; copy number 9: 165; copy number 11: 128; copy number 12: 1; copy number 14: 38; copy number 15: 195; copy number 18: 9; copy number 25: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HG-01A-11D-A26L-01): tumor purity 0.75, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 578 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:83,955,777–85,186,855, 10 genes, copy number 12–18: SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16.
- chr7:135,361,795–136,437,785, 17 genes, copy number 9 (within-gene range 4–9): CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A, AC015987.1, MTPN, RNU6-223P, AC024084.1, AC078845.1, Y_RNA, AC009784.1.
- chr8:113,376,669–113,493,281, 3 genes, copy number 11: AC107890.1, AC055788.2, AC055788.1.
- chr11:71,563,389–71,568,934, 3 genes, copy number 11: AP000867.5, KRTAP5-10, AP000867.1.
- chr11:71,579,728–71,579,848, 1 gene, copy number 11: KRTAP5-14P.
- chr15:87,325,829–87,703,852, 4 genes, copy number 15 (within-gene range 5–15): AC020687.1, RNU6-185P, LINC00052, AC103871.1.
- chr15:89,087,459–100,437,914, 267 genes, copy number 11–25 (within-gene range 5–25) (broad region; genes not listed).
- chr22:15,290,718–21,045,017, 273 genes, copy number 9–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
